Somatic mutation profile of tumor specimen 0DS4M8 from CCDI case PBCDVT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Overlapping lesion of connective, subcutaneous and other soft tissues; Age at diagnosis: 7.2 years (2,628 days).
Specimen 0DS4M8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58b62c72-b7b6-40de-a445-85973b10cef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4MG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5a4a4db-de7b-4042-880e-44e9c635c306

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9L | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1419059462; called by muse, mutect2, varscan2
- MYO15A | c.2544G>A p.S848= | Silent (SNP) | VAF 107/258 reads (41%) | called by muse, mutect2, varscan2
